Somatic mutation profile of tumor specimen C3L-03467-01 (aliquot CPT0188610006) from CPTAC case C3L-03467, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIC1; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 73.3 years (26,781 days).
Specimen C3L-03467-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b01f44ff-94fc-47e2-8219-80b1e1cb2450.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03467-31 (Blood Derived Normal), aliquot CPT0183190002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8627e327-88a2-442d-941b-d0dee021e453

The open-access MAF lists 79 somatic variants for this specimen: 50 protein-altering or splice-affecting, 22 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 22, Nonsense Mutation 3, RNA 3, Frame Shift Del 2, Intron 2, 5'Flank 1, 5'UTR 1, Frame Shift Ins 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 43/145 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LIPA | c.594dup p.A199Cfs*13 | Frame Shift Ins (INS) | VAF 148/427 reads (35%) | catalogued as rs780495201; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 48/238 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 190/699 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADCY2 | c.1784C>T p.T595M | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.34); catalogued as rs765258346, COSV57878323; called by muse, mutect2, varscan2
- APBA2 | c.1280C>T p.T427M | Missense Mutation (SNP) | VAF 39/676 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375339761; called by muse, mutect2
- CABIN1 | c.950C>T p.T317M | Missense Mutation (SNP) | VAF 60/692 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1056788500, COSV54088980; called by muse, mutect2
- DAO | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 95/491 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as rs888461072, COSV57321715; called by muse, mutect2, varscan2
- FBN3 | c.103G>T p.G35W | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV54472210; called by muse, mutect2, varscan2
- GCAT | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 130/242 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs374598324; called by muse, mutect2, varscan2
- IRAK1 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs200423500, COSV57655131; called by muse, mutect2
- KLHDC2 | c.722G>C p.R241T | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV53586867; called by muse, mutect2, varscan2
- LCLAT1 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 113/228 reads (50%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.543); catalogued as rs375650694; called by muse, mutect2, varscan2
- LRRC4B | c.2038G>T p.G680C | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.922); catalogued as COSV65350492; called by muse, mutect2, varscan2
- MST1R | c.3323G>A p.R1108Q | Missense Mutation (SNP) | VAF 97/334 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs147999292; called by muse, mutect2, varscan2
- NKAP | c.1204C>T p.R402* | Nonsense Mutation (SNP) | VAF 31/168 reads (18%) | catalogued as COSV57630491, COSV57630700; called by muse, mutect2, varscan2
- PER1 | c.3775A>G p.K1259E | Missense Mutation (SNP) | VAF 75/245 reads (31%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.003); catalogued as rs1398364032; called by muse, mutect2, varscan2
- POMGNT2 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs763182041; called by muse, mutect2
- PROSER2 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 90/629 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs375679878; called by muse, mutect2, varscan2
- RSPO3 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 15/211 reads (7%) | catalogued as rs778013219; called by muse, mutect2
- SPDYE4 | c.710C>G p.S237C | Missense Mutation (SNP) | VAF 31/366 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV60905129; called by muse, mutect2
- SPECC1L | c.2948C>T p.T983M | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs559868205; called by muse, mutect2, varscan2
- TBX4 | c.1126C>A p.Q376K | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as COSV99540603; called by muse, mutect2, varscan2
- TICRR | c.3512C>A p.S1171* | Nonsense Mutation (SNP) | VAF 24/186 reads (13%) | catalogued as COSV99176747; called by muse, mutect2, varscan2
- TLE3 | c.1942C>T p.R648W | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1454174811; called by muse, mutect2, varscan2
- TNFSF13 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 38/329 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as rs1358719227; called by muse, mutect2, varscan2
- VARS1 | c.1193G>C p.R398P | Missense Mutation (SNP) | VAF 106/277 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs559643914; called by muse, mutect2, varscan2
- CHMP2A | c.428_430del p.M143del | In Frame Del (DEL) | VAF 30/296 reads (10%) | called by pindel, varscan2
- CPAMD8 | c.2320C>G p.L774V (on ENST00000651564; = p.L727V on NM_015692.5) | Missense Mutation (SNP) | VAF 55/233 reads (24%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DNASE1L2 | c.23T>G p.L8R | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- DSCAM | c.2071A>C p.K691Q | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- FAM131C | c.125G>C p.C42S | Missense Mutation (SNP) | VAF 48/575 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- GRM3 | c.2045T>C p.F682S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KRT33B | c.1105T>A p.S369T | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- MROH9 | c.1553G>C p.R518T | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NBPF11 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 78/805 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PALM3 | c.278C>A p.S93Y (on ENST00000340790; = p.S108Y on NM_001145028.2) | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PIK3R5 | c.1704_1708del p.S568Rfs*19 | Frame Shift Del (DEL) | VAF 91/298 reads (31%) | called by mutect2, pindel, varscan2
- PITPNM1 | c.1255C>G p.L419V | Missense Mutation (SNP) | VAF 51/250 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- PPP1R3D | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 72/129 reads (56%) | SIFT tolerated (0.53); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- PPP1R7 | c.601_616del p.I201Pfs*2 | Frame Shift Del (DEL) | VAF 11/110 reads (10%) | called by mutect2, pindel, varscan2
- PRRG3 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCN10A | c.4170C>A p.D1390E | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SCN10A | c.4169A>G p.D1390G | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- TCF7L2 | c.1186C>G p.Q396E (on ENST00000355995 / NM_001367943.1; = p.Q373E on NM_030756.5) | Missense Mutation (SNP) | VAF 60/273 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TDRD6 | c.5404G>C p.V1802L | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2
- TNFRSF21 | c.1139G>C p.G380A | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.2); called by muse, mutect2
- TRPC4 | c.1018T>C p.F340L | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TTLL11 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- XAGE2 | c.-7G>A | Splice Region (SNP) | VAF 14/356 reads (4%) | called by muse, mutect2
- ATP13A1 | c.354G>C p.G118= | Silent (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2, varscan2
- CDC45 | c.144G>A p.T48= | Silent (SNP) | VAF 75/180 reads (42%) | called by muse, mutect2, varscan2
- CIITA | c.801C>A p.P267= | Silent (SNP) | VAF 11/245 reads (4%) | called by muse, mutect2
- CPSF1 | c.3552G>A p.S1184= | Silent (SNP) | VAF 75/261 reads (29%) | catalogued as rs369183467; called by muse, mutect2, varscan2
- CRAT | c.1833C>T p.L611= | Silent (SNP) | VAF 74/287 reads (26%) | called by muse, mutect2, varscan2
- DNASE1L2 | c.22C>T p.L8= | Silent (SNP) | VAF 46/144 reads (32%) | called by muse, mutect2, varscan2
- EYA2 | c.915C>T p.G305= | Silent (SNP) | VAF 72/207 reads (35%) | catalogued as rs1204464725; called by muse, mutect2, varscan2
- GAL3ST1 | c.1134C>G p.L378= | Silent (SNP) | VAF 129/421 reads (31%) | catalogued as COSV100143052; called by muse, mutect2, varscan2
- GOLGA6L2 | c.2367T>C p.D789= | Silent (SNP) | VAF 148/704 reads (21%) | called by muse, varscan2
- HEATR5B | c.3487C>A p.R1163= | Silent (SNP) | VAF 36/462 reads (8%) | catalogued as rs147083195, COSV51849794; called by muse, mutect2
- HMCN2 | c.2259G>A p.A753= | Silent (SNP) | VAF 34/158 reads (22%) | catalogued as rs531055176; called by muse, mutect2, varscan2
- HOXB7 | c.93T>C p.S31= | Silent (SNP) | VAF 24/44 reads (55%) | called by muse, mutect2, varscan2
- IDH1 | c.441T>A p.P147= | Silent (SNP) | VAF 38/390 reads (10%) | called by muse, mutect2, varscan2
- NTN5 | c.1431C>T p.G477= | Silent (SNP) | VAF 119/208 reads (57%) | catalogued as rs774400591, COSV54307502; called by muse, mutect2, varscan2
- PLEKHA5 | c.2013A>G p.L671= | Silent (SNP) | VAF 60/132 reads (45%) | catalogued as rs1370050120; called by muse, mutect2, varscan2
- PRPF6 | c.2022C>T p.T674= | Silent (SNP) | VAF 87/967 reads (9%) | catalogued as rs151209735; called by muse, mutect2
- SCARF1 | c.1767G>A p.S589= | Silent (SNP) | VAF 26/308 reads (8%) | catalogued as rs952398138, COSV99557042; called by muse, mutect2
- SHROOM1 | c.2454C>T p.D818= (on ENST00000378679 / NM_001172700.2; = p.D813= on NM_133456.2) | Silent (SNP) | VAF 161/361 reads (45%) | catalogued as rs756169500, COSV60580725; called by muse, mutect2, varscan2
- SYNJ1 | c.4215T>C p.V1405= | Silent (SNP) | VAF 85/224 reads (38%) | called by mutect2, varscan2
- TMEM63B | c.1323C>G p.L441= | Silent (SNP) | VAF 47/337 reads (14%) | called by muse, mutect2, varscan2
- ZNF559 | c.1350G>A p.S450= | Silent (SNP) | VAF 19/296 reads (6%) | catalogued as rs533736412; called by muse, mutect2
- ZNF786 | c.1080G>A p.A360= | Silent (SNP) | VAF 76/167 reads (46%) | catalogued as rs1459820239; called by muse, mutect2, varscan2
- AC073348.1 | n.36T>A | RNA (SNP) | VAF 35/66 reads (53%) | called by muse, mutect2, varscan2
- DENND10P1 | n.894G>A | RNA (SNP) | VAF 80/383 reads (21%) | called by muse, mutect2, varscan2
- FAM104B | c.20+140C>T | Intron (SNP) | VAF 161/488 reads (33%) | called by muse, mutect2, varscan2
- GNAT1 | c.-31T>C | 5'UTR (SNP) | VAF 47/218 reads (22%) | called by muse, mutect2, varscan2
- NEU4 | chr2:241809144 C>G | 5'Flank (SNP) | VAF 30/349 reads (9%) | called by muse, mutect2
- PRR34 | n.371G>C | RNA (SNP) | VAF 19/166 reads (11%) | catalogued as rs976652138, COSV61549239; called by muse, mutect2, varscan2
- SLC12A8 | c.737-45G>A | Intron (SNP) | VAF 51/275 reads (19%) | catalogued as rs760402468; called by muse, mutect2, varscan2
